Somatic mutation profile of tumor specimen ALCH-B1MC-TTP1-A (aliquot ALCH-B1MC-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1MC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.0 years (24,115 days).
Specimen ALCH-B1MC-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7eb55d6-f8eb-4f95-ae94-88e1459a1924.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1MC-NB1-A (Blood Derived Normal), aliquot ALCH-B1MC-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d0a5cc7-e751-4533-b9b3-d30619052d40

The open-access MAF lists 112 somatic variants for this specimen: 78 protein-altering or splice-affecting, 21 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 21, Nonsense Mutation 12, Intron 6, RNA 4, Splice Region 1, 5'UTR 1, Splice Site 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 16/262 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AKR1D1 | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54337868; called by muse, mutect2
- AMPH | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.724); catalogued as COSV57748838, COSV57757059, COSV57757333; called by muse, mutect2
- ARID1A | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 18/275 reads (7%) | catalogued as COSV61377807; called by muse, mutect2
- ARID4A | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 16/196 reads (8%) | catalogued as COSV62166416; called by muse, mutect2
- BCAS4 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV52815332; called by muse, mutect2
- C12orf40 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61132290; called by muse, mutect2
- CNTN5 | c.583G>T p.G195* | Nonsense Mutation (SNP) | VAF 11/121 reads (9%) | catalogued as COSV54305914; called by muse, mutect2
- COL5A3 | c.4180G>A p.G1394R | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV53412332; called by muse, mutect2
- CRYBG1 | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1306079071; called by muse, mutect2
- CSMD1 | c.3300G>T p.R1100S (on ENST00000520002; = p.R1099S on NM_033225.6) | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100152661; called by muse, mutect2
- CSMD3 | c.7749G>T p.Q2583H (on ENST00000297405 / NM_001363185.1; = p.Q2479H on NM_052900.3) | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV52210194; called by muse, mutect2
- GNAS | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs1376619714, COSV100008076; called by muse, mutect2
- GPR158 | c.3253G>A p.E1085K | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1480573568; called by muse, mutect2
- HECW1 | c.4581G>T p.R1527S | Missense Mutation (SNP) | VAF 19/219 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1243218355; called by muse, mutect2
- JHY | c.1634G>T p.W545L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99913383; called by muse, mutect2
- KIRREL1 | c.807G>C p.E269D | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as COSV63287305, COSV63291354; called by muse, mutect2
- LCE1F | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.09); catalogued as rs200171226, COSV57668856; called by muse, mutect2
- MAP1B | c.2620G>T p.E874* | Nonsense Mutation (SNP) | VAF 18/244 reads (7%) | catalogued as COSV57103118; called by muse, mutect2
- NKRF | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1239388942; called by muse, mutect2
- OR5D18 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV61737970; called by muse, mutect2
- PCDHA13 | c.2195G>T p.C732F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV56505244; called by muse, mutect2
- PCDHA4 | c.2128C>T p.L710F | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV63543602; called by muse, mutect2
- PSG8 | c.1167C>A p.S389R | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV60614315; called by muse, mutect2
- RBM10 | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 11/278 reads (4%) | catalogued as COSV61308721; called by muse, mutect2
- RIN2 | c.2141A>G p.Y714C (on ENST00000255006 / NM_001242581.1; = p.Y665C on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54791399; called by muse, mutect2
- SORCS3 | c.2561G>T p.R854M | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as COSV100863787; called by muse, mutect2
- TDRD6 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.801); catalogued as rs1014505952; called by muse, mutect2
- TGFBR2 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 24/435 reads (6%) | catalogued as COSV55448334; called by muse, mutect2
- TNNT2 | c.883G>A p.G295R (on ENST00000236918; = p.G292R on NM_000364.4) | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs147940106; ClinVar: uncertain significance; called by muse, mutect2
- UQCRC1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 2/22 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs1373560890, COSV52552766; called by muse, mutect2
- ZMYM2 | c.1484G>T p.C495F | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV67033858; called by muse, mutect2
- ZNF667 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV99409897; called by muse, mutect2
- ABCG5 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2
- BCORL1 | c.3277C>G p.Q1093E | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- BRCC3 | c.828G>C p.M276I | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.943); called by muse, mutect2
- CCM2 | c.603G>T p.E201D | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- CDH9 | c.2206G>T p.A736S | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- CHD6 | c.5429T>A p.L1810* | Nonsense Mutation (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- CNTN1 | c.2884A>G p.I962V | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.034); called by muse, mutect2
- DCLK1 | c.510A>T p.K170N | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- DNAI1 | c.1508A>T p.D503V | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ERICH3 | c.3949G>T p.D1317Y | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2
- FANCD2 | c.1704C>G p.F568L | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBN2 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- GABRB2 | c.1166C>A p.T389N | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- HEPH | c.1015G>C p.E339Q (on ENST00000343002; = p.E72Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- IK | c.164C>G p.S55* | Nonsense Mutation (SNP) | VAF 8/210 reads (4%) | called by muse, mutect2
- IL13RA1 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2
- ITGB8 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- KDR | c.3964G>C p.E1322Q | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- MDC1 | c.2595A>T p.L865F | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- MSL3 | c.1381G>T p.V461L (on ENST00000312196 / NM_078629.4; = p.V295L on NM_006800.4) | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2
- MUC16 | c.33070G>T p.G11024W | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.516); called by muse, mutect2
- MXRA5 | c.4867G>A p.E1623K | Missense Mutation (SNP) | VAF 11/248 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- MYO3A | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- NOL8 | c.1388C>G p.S463* | Nonsense Mutation (SNP) | VAF 14/384 reads (4%) | called by muse, mutect2
- NUB1 | c.1449C>G p.N483K | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2
- OR5AR1 | c.257T>A p.L86Q | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR6V1 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.906); called by muse, mutect2
- PAGE2 | c.268G>T p.V90F | Missense Mutation (SNP) | VAF 28/483 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2
- PNN | c.927G>T p.E309D | Missense Mutation (SNP) | VAF 198/548 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- POTEF | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- RAP1GAP | c.-115G>T | Splice Region (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- RYR2 | c.11302G>T p.G3768C | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SALL1 | c.1180C>G p.Q394E | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2
- SLITRK2 | c.2515C>G p.Q839E | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- SUN1 | c.1586G>T p.W529L (on ENST00000405266 / NM_001367651.1; = p.W409L on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); called by muse, mutect2
- SYN3 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D5 | c.442-1G>C p.X148_splice | Splice Site (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- TIMM44 | c.1209C>G p.N403K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- TMEM169 | c.608A>G p.K203R | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMEM183A | c.149T>A p.V50E | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.354); called by muse, mutect2
- TNXB | c.8800G>T p.E2934* (on ENST00000647633; = p.E2687* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- TRPC6 | c.1916T>C p.V639A | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- USP24 | c.7669C>T p.Q2557* | Nonsense Mutation (SNP) | VAF 15/304 reads (5%) | called by muse, mutect2
- USP29 | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- VPS4A | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS8 | c.603G>T p.P201= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV57292914; called by muse, mutect2
- ASL | c.1092C>G p.L364= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as COSV59189169; called by muse, mutect2
- ASPM | c.10317C>T p.T3439= | Silent (SNP) | VAF 11/307 reads (4%) | called by muse, mutect2
- CFAP46 | c.654T>A p.S218= | Silent (SNP) | VAF 18/253 reads (7%) | called by muse, mutect2
- CGAS | c.1323C>T p.A441= | Silent (SNP) | VAF 9/298 reads (3%) | catalogued as rs1211478812; called by muse, mutect2
- CHRNA9 | c.60G>A p.L20= | Silent (SNP) | VAF 12/299 reads (4%) | catalogued as rs1465250892; called by muse, mutect2
- CMTR2 | c.531C>T p.Y177= | Silent (SNP) | VAF 16/175 reads (9%) | called by muse, mutect2
- LMLN | c.1449C>T p.F483= | Silent (SNP) | VAF 32/382 reads (8%) | called by muse, mutect2
- LRCH2 | c.840T>C p.N280= | Silent (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- MTMR1 | c.429G>A p.P143= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as rs782449977; called by muse, mutect2
- MYEF2 | c.639C>G p.L213= | Silent (SNP) | VAF 15/396 reads (4%) | catalogued as rs886985994; called by muse, mutect2
- NAGK | c.138G>A p.V46= | Silent (SNP) | VAF 9/191 reads (5%) | called by muse, mutect2
- OR51B2 | c.123C>T p.G41= | Silent (SNP) | VAF 9/213 reads (4%) | called by muse, mutect2
- OR52E4 | c.838C>T p.L280= | Silent (SNP) | VAF 7/142 reads (5%) | catalogued as COSV57625885; called by muse, mutect2
- PDE8B | c.1173C>T p.H391= | Silent (SNP) | VAF 16/382 reads (4%) | called by muse, mutect2
- PPIP5K1 | c.3807G>A p.Q1269= (on ENST00000396923; = p.Q1244= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/213 reads (7%) | called by muse, mutect2
- PTPRB | c.519C>T p.L173= | Silent (SNP) | VAF 14/173 reads (8%) | catalogued as COSV54238274; called by muse, mutect2
- TAF15 | c.936C>T p.I312= (on ENST00000605844 / NM_139215.3; = p.I309= on NM_003487.4) | Silent (SNP) | VAF 16/436 reads (4%) | called by muse, mutect2
- TAS2R38 | c.804C>A p.P268= | Silent (SNP) | VAF 26/207 reads (13%) | called by muse, mutect2, varscan2
- TM9SF2 | c.1497A>G p.E499= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- ZNF234 | c.1683C>G p.V561= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- ABCA4 | c.-37C>G | 5'UTR (SNP) | VAF 14/274 reads (5%) | called by muse, mutect2
- ARHGEF4 | c.-108-62C>A | Intron (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- DST | c.4297-1837T>C | Intron (SNP) | VAF 12/320 reads (4%) | called by muse, mutect2
- GRHPR | c.734+233C>T | Intron (SNP) | VAF 15/94 reads (16%) | catalogued as rs915142779; called by muse, mutect2, varscan2
- LINC00868 | n.658A>C | RNA (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- NOC2LP2 | n.784A>T | RNA (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2
- NR1I3 | c.238+34G>C | Intron (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- OR2L1P | n.667A>G | RNA (SNP) | VAF 8/167 reads (5%) | called by muse, mutect2
- POMP | chr13:28659106 C>A | 5'Flank (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- RBM44 | c.-98-2183C>G | Intron (SNP) | VAF 16/201 reads (8%) | called by muse, mutect2
- RDX | c.1252-51G>C | Intron (SNP) | VAF 8/132 reads (6%) | catalogued as COSV58193319; called by muse, mutect2
- TUBB7P | n.171C>T | RNA (SNP) | VAF 6/57 reads (11%) | catalogued as rs1162503862; called by muse, mutect2
- XIAP | c.*2398G>A | 3'UTR (SNP) | VAF 23/328 reads (7%) | called by muse, mutect2
